Somatic mutation profile of tumor specimen MMRF_2293_1_BM_CD138pos (aliquot MMRF_2293_1_BM_CD138pos_T1_KHS5U_L11045) from MMRF case MMRF_2293, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.5 years (25,369 days).
Specimen MMRF_2293_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdd25fc5-d8bd-4990-b1a9-b20164554e30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2293_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2293_1_PB_WBC_C2_KHS5U_L11046; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af4daba-1f59-4ca8-855c-ba9690cb3208

The open-access MAF lists 211 somatic variants for this specimen: 85 protein-altering or splice-affecting, 25 silent, 101 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, 3'UTR 47, Intron 33, Silent 25, 5'UTR 8, 5'Flank 6, 3'Flank 4, RNA 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCR | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as COSV59933347; called by muse, mutect2, varscan2
- CPB2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186705993, COSV51677269; called by muse, mutect2, varscan2
- DCST2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 268/652 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373815194; called by muse, mutect2, varscan2
- FNDC1 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV51936201, COSV51940416; called by muse, mutect2, varscan2
- FRY | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371595336, COSV66564596; called by muse, mutect2, varscan2
- GATM | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.762); catalogued as COSV67540423; called by muse, mutect2, varscan2
- IGLON5 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54534379; called by muse, mutect2
- KCTD8 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as rs752490830; called by muse, mutect2, varscan2
- KLHL6 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.105); catalogued as COSV58069503; called by muse, mutect2, varscan2
- KRTAP13-1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374257240, COSV62664445; called by muse, mutect2, varscan2
- LINGO1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1441087058, COSV62438103; called by muse, mutect2, varscan2
- MAP1A | c.6700C>T p.P2234S | Missense Mutation (SNP) | VAF 133/497 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.135); catalogued as COSV55812746; called by muse, mutect2, varscan2
- MCHR2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as rs761446827, COSV56001069; called by muse, mutect2, varscan2
- MICAL3 | c.1957T>G p.F653V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs780137201; called by muse, mutect2, varscan2
- OR7G3 | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1211181362, COSV104398629; called by muse, mutect2, varscan2
- PPP2R2B | c.940C>T p.R314C (on ENST00000394409; = p.R380C on NM_181674.2) | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs768002675, COSV60765065; called by muse, mutect2, varscan2
- RRP1B | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 35/227 reads (15%) | catalogued as rs1318866162; called by muse, mutect2, varscan2
- RYR2 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as rs375218751, COSV63701124; ClinVar: uncertain significance; called by muse, mutect2
- SI | c.4534A>G p.I1512V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as rs1488739530, COSV52286769; called by muse, mutect2, varscan2
- SI | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52278074; called by muse, mutect2, varscan2
- SPTA1 | c.4703G>A p.C1568Y | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs770239726, COSV63748616; called by muse, mutect2, varscan2
- TRPV6 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.084); catalogued as rs983155662; called by muse, mutect2, varscan2
- VSIG10L | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); catalogued as rs1442002314; called by muse, mutect2
- WASF1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV100846822; called by muse, mutect2, varscan2
- WDR27 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV61204686; called by muse, mutect2, varscan2
- XRN2 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV65868004; called by muse, mutect2
- ZSCAN1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 157/285 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs372351161, COSV56603506, COSV56605032, COSV99991543; called by muse, mutect2, varscan2
- ZSCAN10 | c.1600C>T p.R534C (on ENST00000252463; = p.R589C on NM_032805.3) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1017863494, COSV52971419; called by muse, mutect2, varscan2
- ACAP2 | c.2289T>G p.N763K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ARHGAP32 | c.3232G>A p.A1078T (on ENST00000310343 / NM_001378025.1; = p.A729T on NM_014715.4) | Missense Mutation (SNP) | VAF 141/490 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARMH4 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCL3 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CIART | c.521+2T>C p.X174_splice | Splice Site (SNP) | VAF 15/280 reads (5%) | called by muse, mutect2
- CMTM7 | c.98A>C p.E33A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- COL20A1 | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- COL27A1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 99/435 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CYP19A1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CYP4A11 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DACH1 | c.1894G>T p.A632S (on ENST00000619232 / NM_001366712.1; = p.A378S on NM_004392.6) | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.20335G>C p.D6779H (on ENST00000361203 / NM_001374722.1; = p.D4476H on NM_015548.5) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERP29 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FAM205A | c.3107A>T p.K1036M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2
- FAT2 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2
- FGGY | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR9 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- IGKV2-30 | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ING5 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IPO4 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- IPO5 | c.3035C>T p.T1012I | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- KLF2 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KLHL42 | c.291T>A p.D97E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK10 | c.451-1G>A p.X151_splice (on ENST00000359221 / NM_001351625.2; = p.X189_splice on NM_002753.5) | Splice Site (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- MYBPC3 | c.2962G>C p.G988R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO10 | c.4013T>C p.I1338T | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYOT | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYSM1 | c.2470A>C p.K824Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2
- NEK10 | c.3080A>G p.Q1027R | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX2-3 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.045); called by mutect2, varscan2
- OMG | c.1207T>C p.W403R | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4D11 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PKD1L3 | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKNOX2 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLCB2 | c.35A>C p.K12T | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); called by mutect2, varscan2
- PPARA | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PRPF31 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PSMB1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC1 | c.1049A>C p.K350T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSORS1C1 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- PTPRN2 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.054); called by muse, mutect2
- RYR1 | c.1086C>A p.D362E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR3 | c.3817C>T p.H1273Y | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SEMA5B | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SEMA6D | c.1990C>T p.L664F (on ENST00000316364 / NM_153618.2; = p.L602F on NM_020858.2) | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SHARPIN | c.1082A>T p.N361I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK2 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2
- SYNE2 | c.497G>C p.S166T | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TRMT1 | c.1726A>C p.M576L | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.51868_51876del p.W17290_R17292del (on ENST00000591111; = p.W9866_R9868del on NM_003319.4) | In Frame Del (DEL) | VAF 59/192 reads (31%) | called by mutect2, pindel, varscan2
- UBASH3B | c.1182G>T p.R394S | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC5D | c.841A>G p.N281D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- USP32 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WDR7 | c.1871C>A p.P624Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ZNF292 | c.3941dup p.N1314Kfs*3 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- ZNF41 | c.1152dup p.C385Mfs*3 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- ADH1C | c.495G>A p.S165= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as COSV72463507; called by muse, mutect2, varscan2
- ATP2B4 | c.1521C>T p.G507= | Silent (SNP) | VAF 38/359 reads (11%) | called by muse, mutect2, varscan2
- ATP5F1B | c.1092T>G p.A364= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1377014373; called by muse, mutect2, varscan2
- CALD1 | c.255C>T p.N85= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as rs1046037633; called by muse, mutect2, varscan2
- DAB2IP | c.2265C>A p.R755= (on ENST00000408936; = p.R727= on NM_032552.3) | Silent (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- ENAM | c.864G>C p.G288= | Silent (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- FAM178B | c.1393C>T p.L465= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- H4C9 | c.183G>A p.V61= | Silent (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- HOXD13 | c.333G>A p.T111= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as rs1005543758; called by muse, mutect2
- IGSF9 | c.1413C>T p.L471= (on ENST00000368094 / NM_001135050.2; = p.L455= on NM_020789.4) | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs1428724339, COSV63639615, COSV63640729; called by muse, mutect2, varscan2
- KCNJ11 | c.726C>T p.N242= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as rs72554078; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAB21L3 | c.1020G>A p.P340= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as rs202007056; called by muse, mutect2, varscan2
- MAST4 | c.4248G>A p.K1416= (on ENST00000403625 / NM_001164664.2; = p.K1227= on NM_015183.3) | Silent (SNP) | VAF 41/239 reads (17%) | called by muse, mutect2, varscan2
- MED15 | c.552G>A p.Q184= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1236738125, COSV99488045; called by muse, varscan2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- PCDHB1 | c.1860A>G p.R620= | Silent (SNP) | VAF 63/296 reads (21%) | called by muse, mutect2, varscan2
- PTPRD | c.1881G>A p.L627= | Silent (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- PUM2 | c.1275T>A p.L425= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.894T>G p.V298= | Silent (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2358G>C p.P786= | Silent (SNP) | VAF 39/350 reads (11%) | catalogued as COSV100500907; called by muse, mutect2, varscan2
- TELO2 | c.1140G>C p.R380= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- TLCD5 | c.621C>T p.F207= (on ENST00000375095 / NM_001198671.2; = p.F229= on NM_001198670.2) | Silent (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- ZNF180 | c.657A>G p.K219= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99659508; called by muse, mutect2, varscan2
- ZNF454 | c.1116T>A p.T372= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- ZNF668 | c.261G>A p.P87= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as rs569153698; called by muse, mutect2, varscan2
- ACACB | c.6788-808G>A | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ADAM8 | c.-15C>T | 5'UTR (SNP) | VAF 34/78 reads (44%) | catalogued as rs535113696; called by muse, mutect2, varscan2
- ADGRV1 | c.4378+789del | Intron (DEL) | VAF 15/63 reads (24%) | called by mutect2, varscan2
- AGPAT5 | c.*1480A>C | 3'UTR (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- AL355916.3 | c.419+22660G>A | Intron (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2
- AL591135.1 | n.4642G>T | RNA (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- ARL5B | c.*4747G>A | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.401-158C>A | Intron (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2
- ATAT1 | c.1091+90T>G | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- C8orf34 | c.328-1107G>A | Intron (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- CACNA1E | c.*1916T>C | 3'UTR (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- CADM1 | chr11:115504451 G>T | 5'Flank (SNP) | VAF 36/171 reads (21%) | catalogued as rs1565460098; called by muse, mutect2, varscan2
- CD36 | c.-90+228_-90+229insC | Intron (INS) | VAF 18/88 reads (20%) | called by mutect2, pindel*, varscan2
- CHODL | c.*961C>A | 3'UTR (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- CORO7 | c.1578+187G>A | Intron (SNP) | VAF 13/78 reads (17%) | catalogued as rs1449531311; called by muse, varscan2
- CYP11A1 | c.270-2155C>T | Intron (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- DFFA | c.783+106G>A | Intron (SNP) | VAF 116/370 reads (31%) | called by muse, mutect2, varscan2
- DLGAP4 | c.-58G>A | 5'UTR (SNP) | VAF 80/227 reads (35%) | catalogued as rs1422654461, COSV59413963; called by muse, mutect2, varscan2
- DNAJB14 | c.*36T>C | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- DTX1 | c.-193T>C | 5'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- DUSP4 | c.*1640C>T | 3'UTR (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- EML2 | c.21-28T>C | Intron (SNP) | VAF 55/216 reads (25%) | catalogued as rs769393045; called by muse, mutect2, varscan2
- EPS8L2 | c.*475G>A | 3'UTR (SNP) | VAF 78/235 reads (33%) | catalogued as rs570703621; called by muse, mutect2, varscan2
- ERO1A | c.*2609T>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009777 C>A | 5'Flank (SNP) | VAF 65/405 reads (16%) | called by muse, mutect2, varscan2
- ETNK2 | c.1015-57G>T | Intron (SNP) | VAF 53/366 reads (14%) | called by muse, mutect2, varscan2
- FADS1 | c.376-150G>T | Intron (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- FBN1 | c.164+468G>A | Intron (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- FBXW11 | chr5:172006819 G>A | 5'Flank (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- FCN2 | c.*69C>T | 3'UTR (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2, varscan2
- FSD1L | c.*4532G>A | 3'UTR (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- GART | chr21:33543268 C>T | 5'Flank (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- GATAD2A | c.*1850_*1853del | 3'UTR (DEL) | VAF 42/166 reads (25%) | catalogued as rs961338107; called by pindel, varscan2
- GLRA3 | c.*6864G>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- GPC1 | c.167-2350G>A | Intron (SNP) | VAF 19/120 reads (16%) | catalogued as rs1001950068; called by muse, mutect2, varscan2
- GPM6A | c.-23+31357C>T | Intron (SNP) | VAF 84/233 reads (36%) | called by muse, mutect2, varscan2
- GXYLT1 | c.*3727_*3730del | 3'UTR (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- GYPA | c.*1973T>G | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2
- IKZF2 | c.139+277G>C | Intron (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- IQCE | c.*3414G>A | 3'UTR (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- ITGB5 | c.*346G>A | 3'UTR (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.*241dup | 3'UTR (INS) | VAF 13/45 reads (29%) | catalogued as rs201315401; called by mutect2, varscan2
- KIAA0232 | c.*1882C>T | 3'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- LCOR | c.*1760G>C | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- LIF | c.*1810C>T | 3'UTR (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- LTB | c.209-57G>A | Intron (SNP) | VAF 23/83 reads (28%) | catalogued as rs879136053, COSV65815827; called by muse, mutect2, varscan2
- LTB | c.209-58G>T | Intron (SNP) | VAF 22/81 reads (27%) | catalogued as COSV65815493; called by muse, mutect2, varscan2
- MAGEA9B | c.*566A>C | 3'UTR (SNP) | VAF 92/268 reads (34%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*4624G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- MATN1 | c.*1978C>T | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851254 G>T | 5'Flank (SNP) | VAF 54/124 reads (44%) | called by muse, varscan2
- MIR5195 | chr14:106851318 G>A | 5'Flank (SNP) | VAF 48/114 reads (42%) | catalogued as rs184165450; called by muse, varscan2
- MIR9-1HG | n.478T>A | RNA (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- MMP16 | c.*1247T>C | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- MROH7 | c.2965-18G>A | Intron (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- MS4A6A | c.652-193T>A | Intron (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- MTR | c.*3929T>A | 3'UTR (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- NF2 | c.*754G>T | 3'UTR (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- NKAPD1 | c.*227_*228del | 3'UTR (DEL) | VAF 4/33 reads (12%) | catalogued as rs1491340302; called by pindel, varscan2
- NOVA1 | c.447+91T>G | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- NPIPB14P | chr16:69976350 G>T | 3'Flank (SNP) | VAF 39/50 reads (78%) | called by mutect2, varscan2
- NTNG2 | c.*1577T>A | 3'UTR (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+8050del | Intron (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- OR5F2P | n.143T>C | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- OR5M8 | c.*50A>C | 3'UTR (SNP) | VAF 88/280 reads (31%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.*276G>A | 3'UTR (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2394+1974A>T | Intron (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- PGR | c.*1574C>T | 3'UTR (SNP) | VAF 33/104 reads (32%) | catalogued as rs1038540060; called by muse, mutect2, varscan2
- PLA2G1B | c.35-11T>C | Intron (SNP) | VAF 93/361 reads (26%) | called by muse, mutect2, varscan2
- PLCB2 | c.2602+92C>T | Intron (SNP) | VAF 55/173 reads (32%) | called by muse, mutect2, varscan2
- PLCL2 | c.*579A>G | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-193G>T | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PREX2 | c.*1645T>A | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- PRTG | c.2042-14960G>C | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- RASEF | c.*2437A>C | 3'UTR (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- RASSF8 | chr12:26070745 A>G | 3'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- RBM8A | c.*157C>T | 3'UTR (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- RNF175 | c.764+50C>T | Intron (SNP) | VAF 14/109 reads (13%) | catalogued as rs868440243; called by muse, mutect2, varscan2
- RPL37 | c.-35C>T | 5'UTR (SNP) | VAF 106/424 reads (25%) | catalogued as rs537067373, COSV57038641; called by muse, mutect2, varscan2
- RTCA | c.*386T>G | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- SELL | c.*495C>A | 3'UTR (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- SHISA9 | c.564-6860C>A | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- SMTNL2 | chr17:4610597 G>T | 3'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- SPACA6 | c.-61C>G | 5'UTR (SNP) | VAF 10/37 reads (27%) | catalogued as rs941142239; called by muse, mutect2, varscan2
- SYTL2 | c.1459+794T>C | Intron (SNP) | VAF 52/639 reads (8%) | called by muse, mutect2
- TEKT4 | c.-102G>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs574322364; called by muse, mutect2, varscan2
- THNSL1 | c.*804G>C | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- TMEM259 | c.1317+39G>A | Intron (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2
- TMEM38B | c.*1156C>T | 3'UTR (SNP) | VAF 26/159 reads (16%) | catalogued as rs948853865; called by muse, mutect2, varscan2
- TNFRSF10B | c.*445G>C | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TSPAN18 | c.*1220C>T | 3'UTR (SNP) | VAF 52/158 reads (33%) | catalogued as rs1490758672; called by muse, mutect2, varscan2
- UBP1 | chr3:33389181 G>A | 3'Flank (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- UNC13A | c.*2905G>A | 3'UTR (SNP) | VAF 28/133 reads (21%) | catalogued as rs1308122093; called by muse, varscan2
- USP50 | c.-30G>A | 5'UTR (SNP) | VAF 91/481 reads (19%) | called by muse, mutect2, varscan2
- UTP23 | c.*582G>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- WDR37 | c.138+2126C>A | Intron (SNP) | VAF 48/138 reads (35%) | called by muse, mutect2, varscan2
- WEE2 | c.-378A>G | 5'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- XPR1 | c.*5580del | 3'UTR (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- ZBTB42 | c.*1087G>T | 3'UTR (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- ZBTB5 | c.*2032C>A | 3'UTR (SNP) | VAF 34/251 reads (14%) | called by muse, mutect2, varscan2
- ZC3H12B | c.*4544C>T | 3'UTR (SNP) | VAF 26/46 reads (57%) | catalogued as rs1163576346; called by muse, mutect2, varscan2
